Somatic mutation profile of tumor specimen TCGA-D1-A16R-01A (aliquot TCGA-D1-A16R-01A-11D-A12J-09) from TCGA case TCGA-D1-A16R, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 39.6 years (14,465 days).
Specimen TCGA-D1-A16R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20f557a9-a744-4fd8-b318-4c0e30d702a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A16R-10A (Blood Derived Normal), aliquot TCGA-D1-A16R-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9186b027-80be-465b-b613-8548cba38ff6

The open-access MAF lists 47 somatic variants for this specimen: 38 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 8, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.104T>G p.I35S | Missense Mutation (SNP) | VAF 34/108 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62687967, COSV62691314, COSV62693017; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 21/118 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 35/185 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.2702G>T p.C901F | Missense Mutation (SNP) | VAF 128/288 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55881149; called by muse, mutect2, varscan2
- PTEN | c.370T>C p.C124R | Missense Mutation (SNP) | VAF 310/522 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909223, CD097201, CM971271, COSV64288968, COSV64294667, COSV64296578, COSV64297040; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTL6B | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV50514372; called by muse, mutect2
- CACNA1E | c.1881C>T p.G627= | Splice Region (SNP) | VAF 160/392 reads (41%) | catalogued as COSV62389958; called by muse, mutect2, varscan2
- CHI3L1 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs527531482, COSV55137741; called by muse, mutect2, varscan2
- CRK | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as rs748897674, COSV56030280; called by muse, mutect2, varscan2
- CTNNB1 | c.1867C>G p.Q623E | Missense Mutation (SNP) | VAF 204/489 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV62697065; called by muse, mutect2, varscan2
- CYP2S1 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as rs372019122; called by muse, mutect2, varscan2
- DEFB129 | c.458G>T p.R153I | Missense Mutation (SNP) | VAF 157/398 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV55731280, COSV55732084; called by muse, mutect2, varscan2
- EDIL3 | c.167A>C p.D56A | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV56891494; called by muse, mutect2, varscan2
- FANCG | c.826G>A p.G276R | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as COSV62720179; called by muse, mutect2, varscan2
- GAPVD1 | c.4165A>C p.T1389P (on ENST00000394104; = p.T1398P on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/318 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1475102621, COSV52922173; called by muse, mutect2
- HIF1AN | c.254T>C p.I85T | Missense Mutation (SNP) | VAF 82/290 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs989425412, COSV54500076; called by muse, mutect2, varscan2
- HMGCLL1 | c.484-1G>C p.X162_splice | Splice Site (SNP) | VAF 15/132 reads (11%) | catalogued as COSV51443337; called by muse, mutect2, varscan2
- ITLN1 | c.789+1G>A p.X263_splice | Splice Site (SNP) | VAF 7/129 reads (5%) | catalogued as rs1289811119, COSV58274784; called by muse, mutect2
- KCNH7 | c.1324C>T p.R442* | Nonsense Mutation (SNP) | VAF 66/171 reads (39%) | catalogued as COSV59793513; called by muse, mutect2, varscan2
- KCNH7 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV100035243, COSV59793528; called by muse, mutect2, varscan2
- KIF2C | c.559T>C p.S187P | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV64764323; called by muse, mutect2
- KLRK1 | c.189G>A p.M63I | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as COSV53698284; called by muse, mutect2, varscan2
- LAX1 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV65849171; called by muse, mutect2, varscan2
- MYH9 | c.5735G>A p.R1912H | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV53381830; called by muse, mutect2, varscan2
- NLRP1 | c.1399A>G p.I467V | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.217); catalogued as rs1436858589, COSV52563811; called by muse, mutect2, varscan2
- NOTCH3 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV54632079; called by muse, mutect2, varscan2
- PCDHA13 | c.1844C>T p.A615V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.009); catalogued as COSV56493106; called by muse, mutect2
- PTEN | c.505_508del p.P169Vfs*13 | Frame Shift Del (DEL) | VAF 108/400 reads (27%) | catalogued as COSV64294679; called by mutect2, pindel*, varscan2
- RGL1 | c.860C>T p.T287I (on ENST00000360851 / NM_001297672.2; = p.T322I on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV58983111; called by muse, mutect2, varscan2
- RXFP2 | c.1189C>T p.R397* | Nonsense Mutation (SNP) | VAF 201/522 reads (39%) | catalogued as rs769923825, COSV53634640; called by muse, mutect2, varscan2
- SEC24B | c.1291C>A p.P431T | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV54497760; called by muse, mutect2, varscan2
- SETD2 | c.6071G>C p.R2024P | Missense Mutation (SNP) | VAF 154/426 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57433930, COSV57435267; called by muse, mutect2, varscan2
- SLC28A3 | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 117/285 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs570175390, COSV66152782; called by muse, mutect2, varscan2
- SMARCA1 | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 116/311 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64411554; called by muse, mutect2, varscan2
- ST8SIA3 | c.581C>T p.T194M | Missense Mutation (SNP) | VAF 74/186 reads (40%) | PolyPhen probably damaging (0.96); catalogued as rs986505525, COSV60653863; called by muse, mutect2, varscan2
- TRA2A | c.407G>C p.R136P | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51716532; called by muse, mutect2, varscan2
- ZKSCAN4 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 26/258 reads (10%) | catalogued as COSV66023355; called by muse, mutect2
- FZR1 | c.281_285del p.L94Qfs*3 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- ACVR1 | c.993C>A p.A331= | Silent (SNP) | VAF 78/214 reads (36%) | catalogued as COSV55117946; called by mutect2, varscan2
- ANKRD11 | c.645C>T p.D215= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as rs773258799, COSV56359243; called by muse, mutect2, varscan2
- ARID3A | c.705C>A p.L235= | Silent (SNP) | VAF 96/278 reads (35%) | catalogued as COSV55044086, COSV55046380; called by muse, mutect2, varscan2
- FAT3 | c.7678C>A p.R2560= | Silent (SNP) | VAF 71/165 reads (43%) | catalogued as COSV53098372, COSV53145294; called by muse, mutect2, varscan2
- GMPPB | c.969G>T p.V323= (on ENST00000308388 / NM_021971.4; = p.V350= on NM_013334.3) | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV57538204; called by muse, mutect2, varscan2
- PCDHA2 | c.948C>T p.Y316= | Silent (SNP) | VAF 42/128 reads (33%) | catalogued as rs138543529, COSV65366238; called by muse, mutect2, varscan2
- WASHC2C | c.2445C>T p.N815= | Silent (SNP) | VAF 59/772 reads (8%) | catalogued as COSV60490945; called by muse, mutect2
- ZIC4 | c.627G>T p.P209= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as rs767781944, COSV67171279, COSV67172310; called by muse, mutect2, varscan2
- DCHS2 | n.3936T>C | RNA (SNP) | VAF 55/122 reads (45%) | catalogued as COSV61770284; called by muse, mutect2, varscan2
